Somatic mutation profile of tumor specimen 799893aa-d523-4a08-9ea7-611cca (aliquot 799893aa-d523-4a08-9ea7-611cca_D6_1) from CPTAC case 11CO007, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 799893aa-d523-4a08-9ea7-611cca: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d6ad899-cf8d-4201-ba51-6215a432e3d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 784ff553-c9a7-4d30-b747-ffcbdf (Blood Derived Normal), aliquot 784ff553-c9a7-4d30-b747-ffcbdf_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71ce5cb8-cce7-4891-bf39-5fd08fd53f02

The open-access MAF lists 2,765 somatic variants for this specimen: 1,894 protein-altering or splice-affecting, 534 silent, 337 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,309, Silent 534, Frame Shift Del 343, Intron 182, Frame Shift Ins 72, Nonsense Mutation 66, Splice Site 60, 3'UTR 56, RNA 34, Splice Region 30, 5'UTR 30, 5'Flank 24.

Variants (750 of 2,765; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.126del p.L43Cfs*3 | Frame Shift Del (DEL) | VAF 37/177 reads (21%) | catalogued as rs180177171, CM930013, COSV56753003; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- APC | c.4666del p.T1556Lfs*9 | Frame Shift Del (DEL) | VAF 97/532 reads (18%) | catalogued as rs587783031; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ARSA | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 60/267 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs74315480, CM940111; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARX | c.1187del p.P396Lfs*67 | Frame Shift Del (DEL) | VAF 17/92 reads (18%) | catalogued as rs1328291159; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ATM | c.640del p.S214Pfs*16 | Frame Shift Del (DEL) | VAF 74/321 reads (23%) | catalogued as rs786204543; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BCHE | c.1027dup p.T343Nfs*8 | Frame Shift Ins (INS) | VAF 56/271 reads (21%) | catalogued as rs754214624; ClinVar: likely pathogenic; called by mutect2, varscan2
- BRCA2 | c.5665del p.I1889Lfs*20 | Frame Shift Del (DEL) | VAF 54/253 reads (21%) | catalogued as rs397507796, COSV101203995; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CEL | c.1785del p.V596Cfs*111 (on ENST00000673714; = p.V593Cfs*111 on NM_001807.6) | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | catalogued as rs193922638; ClinVar: likely pathogenic; called by mutect2, varscan2
- CFTR | c.3211C>T p.Q1071* | Nonsense Mutation (SNP) | VAF 39/362 reads (11%) | catalogued as rs397508517, CM034791, COSV50043207; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 82/397 reads (21%) | catalogued as rs137852424, CM900089, CM990550, COSV100811708; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 32/144 reads (22%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- IQSEC2 | c.4419dup p.S1474Qfs*133 | Frame Shift Ins (INS) | VAF 7/30 reads (23%) | catalogued as rs1569290954; ClinVar: pathogenic; called by mutect2, varscan2
- KRT5 | c.1649del p.G550Afs*77 | Frame Shift Del (DEL) | VAF 13/121 reads (11%) | catalogued as rs61126080, CD032474; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LDLR | c.2416del p.V806Sfs*123 | Frame Shift Del (DEL) | VAF 60/244 reads (25%) | catalogued as rs773618064; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 63/247 reads (26%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 59/241 reads (24%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PCCA | c.923del p.L308Wfs*14 | Frame Shift Del (DEL) | VAF 37/280 reads (13%) | catalogued as rs573607437; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 51/256 reads (20%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 76/343 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs786201995, CM110141, CM993669, COSV64288588, COSV64289716, COSV64295411; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 85/328 reads (26%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- RUNX2 | c.90del p.S31Pfs*9 | Frame Shift Del (DEL) | VAF 20/127 reads (16%) | catalogued as rs397515538; ClinVar: pathogenic; called by pindel, varscan2
- SLC16A1 | c.41dup p.D15Rfs*34 | Frame Shift Ins (INS) | VAF 64/306 reads (21%) | catalogued as rs606231309; ClinVar: pathogenic; called by mutect2, varscan2
- ABCA3 | c.2200G>A p.A734T | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776927506; called by muse, mutect2, varscan2
- ABCA5 | c.2536A>G p.T846A | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV104429558; called by muse, mutect2, varscan2
- ABCA5 | c.128dup p.L43Ffs*8 | Frame Shift Ins (INS) | VAF 31/126 reads (25%) | catalogued as rs751512043; called by mutect2, varscan2
- ABCA8 | c.371T>C p.I124T | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs1380247041; called by muse, mutect2, varscan2
- ABCB8 | c.1507G>A p.V503M (on ENST00000297504 / NM_001282291.2; = p.V486M on NM_007188.5) | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs771537834; called by muse, mutect2, varscan2
- ABCD3 | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 83/372 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs766791159, COSV64642475; called by muse, mutect2, varscan2
- ABHD1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs758121634; called by muse, mutect2, varscan2
- ACACB | c.3862G>A p.V1288M | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs754810954, COSV58128430; called by muse, mutect2, varscan2
- ACO1 | c.2302G>A p.V768I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as rs371291915; called by muse, mutect2, varscan2
- ACOT4 | c.506del p.G169Afs*20 | Frame Shift Del (DEL) | VAF 41/209 reads (20%) | catalogued as COSV58336037; called by mutect2, pindel, varscan2
- ACSM5 | c.323del p.G108Vfs*11 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs746947661, COSV59374153; called by mutect2, pindel, varscan2
- ACSS1 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as rs144423103; called by muse, mutect2, varscan2
- ACVR2A | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99604390; called by muse, mutect2, varscan2
- ADAMTS16 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs377507889; called by muse, mutect2, varscan2
- ADAMTS2 | c.2440G>A p.G814S | Missense Mutation (SNP) | VAF 23/162 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.048); catalogued as rs778295250, COSV52373996; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2800G>A p.G934R | Missense Mutation (SNP) | VAF 89/370 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as rs959562415; called by muse, mutect2, varscan2
- ADAMTSL4 | c.963dup p.T322Dfs*10 | Frame Shift Ins (INS) | VAF 27/167 reads (16%) | catalogued as rs748115277; called by mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 14/72 reads (19%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRA2 | c.3345del p.S1116Pfs*187 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | catalogued as rs977678327; called by mutect2, pindel, varscan2
- ADGRG4 | c.1578A>C p.E526D | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.171); catalogued as rs866815596; called by muse, mutect2
- ADGRV1 | c.4165A>G p.T1389A | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV104434947; called by muse, varscan2
- AKAP12 | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0.005); catalogued as rs1477905270; called by muse, mutect2, varscan2
- AKAP6 | c.5611G>A p.E1871K | Missense Mutation (SNP) | VAF 70/287 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as COSV55210240; called by muse, mutect2, varscan2
- AL441992.2 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs766480924, COSV56916082; called by muse, mutect2
- AL592490.1 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs996027549; called by muse, mutect2, varscan2
- ALG10 | c.438del p.F146Lfs*20 | Frame Shift Del (DEL) | VAF 84/444 reads (19%) | catalogued as rs1163730964; called by mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 55/237 reads (23%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMBRA1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV54051060; called by muse, mutect2, varscan2
- AMOTL2 | c.1358G>A p.R453Q | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs371849038; called by muse, mutect2, varscan2
- AMPD3 | c.214G>A p.A72T (on ENST00000396553 / NM_001025389.2; = p.A81T on NM_000480.3) | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs762457397, COSV67331388; called by mutect2, varscan2
- ANK2 | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758980553, COSV52149307; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.1175A>G p.N392S | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs1414218772; called by muse, mutect2, varscan2
- ANKRD36C | c.4334C>T p.T1445M | Missense Mutation (SNP) | VAF 125/466 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.788); catalogued as rs756398168; called by muse, mutect2, varscan2
- ANKRD49 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 83/362 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs893157953; called by muse, mutect2, varscan2
- ANO8 | c.3253C>T p.R1085W | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs754345088; called by muse, mutect2, varscan2
- APLP2 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs775154305; called by muse, mutect2, varscan2
- ARAP1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868175436, COSV61993590; called by muse, mutect2, varscan2
- ARAP2 | c.1487+2T>C p.X496_splice | Splice Site (SNP) | VAF 26/120 reads (22%) | catalogued as rs768092006; called by muse, mutect2, varscan2
- ARHGAP23 | c.2131G>A p.G711S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.409); catalogued as rs1254539950; called by muse, mutect2, varscan2
- ARHGEF11 | c.3232del p.V1078Cfs*35 | Frame Shift Del (DEL) | VAF 15/88 reads (17%) | catalogued as COSV100168158; called by mutect2, pindel, varscan2
- ARHGEF12 | c.3070G>T p.G1024W | Missense Mutation (SNP) | VAF 32/162 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63107038; called by muse, mutect2, varscan2
- ARHGEF38 | c.1482C>A p.S494R | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.606); catalogued as rs868660189; called by muse, mutect2, varscan2
- ARID2 | c.109del p.I37Sfs*21 | Frame Shift Del (DEL) | VAF 32/135 reads (24%) | catalogued as COSV57601825; called by mutect2, pindel, varscan2
- ARID3A | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV55045872; called by muse, mutect2, varscan2
- ARMC4 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs191594899, COSV53464637, COSV53465076; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARMH1 | c.317T>C p.L106P | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557531975; called by muse, mutect2, varscan2
- ASCC3 | c.489dup p.G164Wfs*2 | Frame Shift Ins (INS) | VAF 54/361 reads (15%) | catalogued as rs747570359; called by mutect2, varscan2
- ASIC5 | c.586-1G>T p.X196_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | catalogued as COSV72232542; called by muse, mutect2, varscan2
- ASPSCR1 | c.1574del p.P525Lfs*11 | Frame Shift Del (DEL) | VAF 12/121 reads (10%) | catalogued as rs770691166; called by mutect2, varscan2
- ASTN1 | c.566C>A p.P189H | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99922138; called by muse, mutect2, varscan2
- ASXL2 | c.4046A>G p.Q1349R | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.255); catalogued as rs373784825; called by muse, mutect2, varscan2
- ASZ1 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.146); catalogued as rs1403771930; called by muse, mutect2, varscan2
- ATG2A | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs767644437, COSV101034813; called by muse, mutect2, varscan2
- ATM | c.7532T>A p.I2511N | Missense Mutation (SNP) | VAF 66/334 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1486563159, COSV53742385; called by muse, mutect2, varscan2
- ATP2B2 | c.2090C>T p.P697L (on ENST00000352432; = p.P663L on NM_001683.5) | Missense Mutation (SNP) | VAF 68/282 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751442343, COSV59492431; called by muse, mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 33/252 reads (13%) | catalogued as rs769726180; called by mutect2, varscan2
- ATP8B2 | c.1630C>T p.R544C (on ENST00000672630; = p.R511C on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as rs750741796, COSV59246529; called by muse, mutect2, varscan2
- ATP8B2 | c.3376C>T p.P1126S (on ENST00000672630; = p.P1093S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63832033; called by muse, mutect2, varscan2
- ATP8B3 | c.3355G>A p.V1119M | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.421); catalogued as rs372550572; called by muse, mutect2, varscan2
- ATXN1L | c.1623dup p.E542Rfs*47 | Frame Shift Ins (INS) | VAF 38/171 reads (22%) | catalogued as rs775793808; called by mutect2, pindel, varscan2
- B4GALNT4 | c.421C>A p.L141M | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as COSV100327474; called by muse, mutect2, varscan2
- B4GALNT4 | c.918del p.R307Vfs*100 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | catalogued as rs770737105, COSV57327371; called by mutect2, varscan2
- BAG3 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs749406496; called by muse, varscan2
- BAG5 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 119/446 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.499); catalogued as COSV54572804; called by muse, mutect2, varscan2
- BATF3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs764402872, COSV54659588; called by muse, mutect2, varscan2
- BCL9L | c.3380del p.P1127Hfs*21 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | catalogued as rs751794665; called by mutect2, varscan2
- BID | c.363T>C p.D121= (on ENST00000317361 / NM_197966.2; = p.D75= on NM_001196.4) | Splice Region (SNP) | VAF 39/117 reads (33%) | catalogued as rs778564091; called by muse, mutect2, varscan2
- BLM | c.2268del p.D757Tfs*4 | Frame Shift Del (DEL) | VAF 102/435 reads (23%) | catalogued as rs747341586; called by mutect2, pindel, varscan2
- BNC2 | c.2311G>A p.V771I | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs754125807, COSV66141151; called by muse, mutect2, varscan2
- BPIFB3 | c.1148C>T p.S383F | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV64956702; called by muse, mutect2, varscan2
- BRINP3 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs553670519, COSV66533368; called by muse, mutect2, varscan2
- BTBD16 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373964027; called by muse, mutect2, varscan2
- C11orf53 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs565783566; called by muse, mutect2, varscan2
- C15orf39 | c.2912C>T p.P971L | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.998); catalogued as COSV62297695; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 22/117 reads (19%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- C4orf47 | c.808_810del p.D270del | In Frame Del (DEL) | VAF 42/243 reads (17%) | catalogued as rs776497400; called by pindel, varscan2
- C5orf34 | c.546A>G p.I182M | Missense Mutation (SNP) | VAF 107/497 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100175370; called by muse, mutect2, varscan2
- C8orf34 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs568088256; called by muse, mutect2, varscan2
- CACHD1 | c.3704del p.P1235Lfs*7 | Frame Shift Del (DEL) | VAF 63/229 reads (28%) | catalogued as rs764948820; called by mutect2, pindel, varscan2
- CACNG7 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV55813458; called by muse, mutect2, varscan2
- CAD | c.3157C>T p.R1053W | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99255942; called by muse, mutect2
- CALN1 | c.136C>T p.R46W (on ENST00000329008 / NM_001017440.3; = p.R88W on NM_031468.4) | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61119319; called by muse, mutect2, varscan2
- CAMK1D | c.1039+4C>T | Splice Region (SNP) | VAF 17/82 reads (21%) | catalogued as rs373315791; called by muse, mutect2, varscan2
- CAMTA1 | c.4384G>A p.E1462K | Missense Mutation (SNP) | VAF 29/169 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.06); catalogued as rs771443655; called by muse, mutect2, varscan2
- CAPS2 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV60828441; called by muse, mutect2, varscan2
- CARD11 | c.1703del p.P568Rfs*32 | Frame Shift Del (DEL) | VAF 35/149 reads (23%) | catalogued as COSV62755623, COSV62756557; called by mutect2, pindel, varscan2
- CASP14 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141847530; called by muse, mutect2, varscan2
- CCDC150 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as rs1192556326; called by muse, mutect2, varscan2
- CCDC169 | c.256dup p.I86Nfs*8 | Frame Shift Ins (INS) | VAF 63/344 reads (18%) | catalogued as rs1250970675; called by mutect2, pindel, varscan2
- CCDC170 | c.1914del p.K638Nfs*24 | Frame Shift Del (DEL) | VAF 54/256 reads (21%) | catalogued as rs751612825; called by mutect2, pindel, varscan2
- CCDC180 | c.2025dup p.S676Ifs*6 | Frame Shift Ins (INS) | VAF 60/297 reads (20%) | catalogued as rs757001908; called by mutect2, pindel, varscan2
- CCDC6 | c.1237T>C p.S413P | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); catalogued as rs757953028; called by muse, mutect2, varscan2
- CCDC73 | c.2683del p.T895Lfs*8 | Frame Shift Del (DEL) | VAF 79/397 reads (20%) | catalogued as rs764792181; called by mutect2, pindel, varscan2
- CCL21 | c.325del p.A109Pfs*89 | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | catalogued as rs777471870; called by mutect2, pindel, varscan2
- CCL3L3 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1264839370; called by muse, mutect2, varscan2
- CCT5 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as rs200430696, COSV54723239, COSV54723403; called by muse, mutect2, varscan2
- CD109 | c.3211T>C p.S1071P | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs768515799; called by muse, mutect2, varscan2
- CD1E | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as rs764692539, COSV63769980; called by muse, mutect2, varscan2
- CD37 | c.142+10del | Splice Region (DEL) | VAF 16/131 reads (12%) | catalogued as rs1458592495; called by mutect2, pindel, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 22/152 reads (14%) | catalogued as rs773911500; called by mutect2, pindel, varscan2
- CDC37 | c.332G>T p.S111I | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.119); catalogued as rs772075527; called by muse, mutect2, varscan2
- CDC42EP4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs572509297, COSV59962189; called by muse, mutect2, varscan2
- CDH12 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs141662751, COSV66458909; called by muse, mutect2, varscan2
- CDH24 | c.771del p.K258Sfs*36 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs753422808; called by mutect2, pindel, varscan2
- CDKN1B | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 90/527 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.451); catalogued as COSV57430603; called by muse, mutect2, varscan2
- CDS1 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV55688935; called by muse, mutect2, varscan2
- CEACAM5 | c.1802del p.P601Qfs*68 | Frame Shift Del (DEL) | VAF 38/148 reads (26%) | catalogued as rs782698410, COSV55750352; called by mutect2, varscan2
- CELSR2 | c.3883C>T p.R1295W | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs747996755, COSV54767913; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as rs1325731082; called by mutect2, varscan2
- CENPN | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746494487, COSV100001463, COSV55141857; called by muse, mutect2, varscan2
- CFAP54 | c.4886G>A p.R1629H | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs183243311, COSV100733270, COSV61570724; called by muse, mutect2, varscan2
- CFAP74 | c.2688A>G p.I896M | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs778484691; called by muse, mutect2, varscan2
- CFAP91 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs562410253, COSV56341898, COSV99847226; called by muse, mutect2, varscan2
- CHAF1B | c.734A>G p.D245G | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs761823048; called by muse, mutect2, varscan2
- CHD8 | c.989C>T p.A330V (on ENST00000646647 / NM_001170629.2; = p.A51V on NM_020920.4) | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1304967976; called by muse, mutect2, varscan2
- CHGA | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 58/230 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as rs532226129; called by muse, mutect2, varscan2
- CHRNA1 | c.830T>C p.V277A (on ENST00000261007 / NM_001039523.3; = p.V252A on NM_000079.4) | Missense Mutation (SNP) | VAF 70/294 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99650705; called by muse, mutect2, varscan2
- CIITA | c.1963G>C p.G655R | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as rs919087827; called by mutect2, varscan2
- CIT | c.3241C>T p.R1081W | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs765007099; called by muse, mutect2, varscan2
- CLDND1 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 50/218 reads (23%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.979); catalogued as rs1472157425; called by muse, mutect2, varscan2
- CLGN | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.596); catalogued as rs199546559; called by muse, mutect2, varscan2
- CLK1 | c.140_143del p.N47Tfs*15 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as rs1418364586; called by mutect2, pindel, varscan2
- CLPSL1 | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV65814701; called by muse, mutect2, varscan2
- CMYA5 | c.6095C>T p.S2032F | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as rs777750580, COSV71410247; called by muse, mutect2
- CNGA3 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 76/351 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs759775948; called by muse, mutect2, varscan2
- CNKSR3 | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.602); catalogued as rs1372802757; called by muse, mutect2, varscan2
- CNNM1 | c.1883A>G p.Y628C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.865); catalogued as COSV63201844; called by muse, mutect2, varscan2
- COL11A1 | c.2218C>T p.Q740* | Nonsense Mutation (SNP) | VAF 50/264 reads (19%) | catalogued as COSV62191641; called by muse, mutect2, varscan2
- COL18A1 | c.1438G>A p.G480R (on ENST00000359759 / NM_130444.3; = p.G245R on NM_030582.4) | Missense Mutation (SNP) | VAF 50/240 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.901); catalogued as rs771267104; called by muse, mutect2, varscan2
- COL22A1 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs753469570, COSV100280787; called by muse, mutect2, varscan2
- COL25A1 | c.1657-3del | Splice Region (DEL) | VAF 20/81 reads (25%) | catalogued as rs760493024; called by mutect2, varscan2
- COL3A1 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 74/382 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs371583734, CM158341; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- COL4A1 | c.4208C>T p.A1403V | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.173); catalogued as rs1482566742; called by muse, mutect2, varscan2
- COL4A1 | c.1943dup p.G649Wfs*53 | Frame Shift Ins (INS) | VAF 85/412 reads (21%) | catalogued as rs989816029; called by mutect2, varscan2
- COL4A6 | c.3280G>T p.G1094C | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57868010; called by muse, varscan2
- COL5A2 | c.3653G>A p.G1218D | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100880066; called by muse, mutect2, varscan2
- COL6A1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 120/454 reads (26%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.611); catalogued as rs569642530, COSV62615138; called by muse, mutect2, varscan2
- COL6A3 | c.8765C>A p.P2922H | Missense Mutation (SNP) | VAF 105/451 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV55111205, COSV99796381; called by muse, mutect2, varscan2
- COL6A3 | c.3892G>A p.A1298T | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.217); catalogued as rs770250670, COSV55103442; called by muse, mutect2
- COL6A3 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 62/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369379463, COSV55093992; called by muse, mutect2, varscan2
- CORO6 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.098); catalogued as COSV52174555; called by muse, mutect2
- COX10 | c.1244G>A p.S415N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55405029; called by muse, mutect2, varscan2
- CREB5 | c.766G>T p.G256* (on ENST00000357727 / NM_182898.4; = p.G249* on NM_004904.3) | Nonsense Mutation (SNP) | VAF 30/107 reads (28%) | catalogued as COSV63223525; called by muse, mutect2, varscan2
- CRP | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.452); catalogued as COSV99660511; called by muse, mutect2, varscan2
- CRYBA2 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as COSV55386920, COSV55387252; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs747248693; called by mutect2, varscan2
- CSF2RA | c.569A>C p.N190T | Missense Mutation (SNP) | VAF 85/433 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.1); catalogued as COSV62623759; called by muse, mutect2, varscan2
- CSH2 | c.79G>A p.V27I | Missense Mutation (SNP) | VAF 78/720 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.312); catalogued as rs570707903, COSV61080072, COSV61081106; called by muse, varscan2
- CSPG4 | c.2576A>G p.Y859C | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57901497; called by muse, mutect2, varscan2
- CSPG5 | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs1027348370; called by muse, mutect2
- CSPP1 | c.869G>A p.G290D (on ENST00000676605; = p.G249D on NM_024790.6) | Missense Mutation (SNP) | VAF 77/385 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs755596160; called by muse, mutect2, varscan2
- CSRNP1 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs978846651, COSV99826880, COSV99827088; called by muse, mutect2, varscan2
- CSTF2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.24); catalogued as COSV65895154; called by muse, mutect2, varscan2
- CT47B1 | c.251A>G p.D84G | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs757180378; called by mutect2, varscan2
- CTAGE9 | c.176dup p.L59Ffs*6 | Frame Shift Ins (INS) | VAF 92/462 reads (20%) | catalogued as rs752217831; called by mutect2, varscan2
- CTDP1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1253336959; called by muse, mutect2, varscan2
- CTDP1 | c.1106C>A p.P369H | Missense Mutation (SNP) | VAF 44/260 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.325); catalogued as COSV50009720; called by muse, mutect2, varscan2
- CTNND2 | c.2219C>T p.T740M | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs781426065; called by muse, mutect2, varscan2
- CUX1 | c.1289del p.P430Lfs*27 | Frame Shift Del (DEL) | VAF 42/98 reads (43%) | catalogued as rs782381199; called by mutect2, pindel, varscan2
- CWC27 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101126568; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | catalogued as rs756254049; called by mutect2, pindel, varscan2
- CYFIP2 | c.13G>A p.V5I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.369); catalogued as rs1421838253, COSV59050632; called by muse, mutect2, varscan2
- CYP2A13 | c.806A>G p.D269G | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768082507; called by muse, mutect2, varscan2
- CYP2A7 | c.1370T>C p.M457T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs753597342; called by muse, mutect2, varscan2
- CYP2C9 | c.643-2A>G p.X215_splice | Splice Site (SNP) | VAF 82/308 reads (27%) | catalogued as COSV53253731; called by muse, mutect2, varscan2
- DAGLA | c.803G>T p.G268V | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226627854; called by muse, mutect2
- DCAF8L2 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.078); catalogued as rs746501868; called by muse, mutect2, varscan2
- DCBLD2 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs977581038; called by muse, mutect2, varscan2
- DDX5 | c.1358T>C p.V453A | Missense Mutation (SNP) | VAF 65/290 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56747738, COSV99858180; called by muse, mutect2, varscan2
- DDX50 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 41/163 reads (25%) | catalogued as COSV65293267; called by muse, mutect2, varscan2
- DENND1C | c.491del p.P164Lfs*29 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs553532837; called by mutect2, varscan2
- DFFA | c.783+7G>A | Splice Region (SNP) | VAF 19/104 reads (18%) | catalogued as rs772455668; called by muse, mutect2, varscan2
- DIAPH3 | c.2822del p.P941Lfs*10 (on ENST00000400324 / NM_001042517.2; = p.P678Lfs*10 on NM_030932.3) | Frame Shift Del (DEL) | VAF 86/413 reads (21%) | catalogued as COSV99933943; called by mutect2, pindel, varscan2
- DISP3 | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs775462722, COSV53819266; called by muse, mutect2, varscan2
- DMRT2 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs763655980, COSV99426113; called by muse, mutect2, varscan2
- DNAH14 | c.8153A>G p.Y2718C (on ENST00000445597; = p.Y3521C on NM_001367479.1) | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416451343; called by muse, mutect2, varscan2
- DNAH3 | c.6467C>A p.P2156H | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54518595; called by muse, mutect2, varscan2
- DNAH5 | c.13771G>A p.V4591I | Missense Mutation (SNP) | VAF 57/379 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1420616107; called by muse, mutect2, varscan2
- DNAH5 | c.11771C>A p.S3924* | Nonsense Mutation (SNP) | VAF 110/460 reads (24%) | catalogued as COSV54221650; called by muse, mutect2, varscan2
- DNAH9 | c.6520C>T p.R2174C | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs143563564; called by muse, mutect2, varscan2
- DND1 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs1167644251, COSV100298146; called by muse, mutect2, varscan2
- DOCK10 | c.1122del p.D375Ifs*8 | Frame Shift Del (DEL) | VAF 58/226 reads (26%) | catalogued as rs750262341; called by mutect2, varscan2
- DOCK3 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as rs769396900; called by muse, mutect2, varscan2
- DOCK3 | c.3715C>T p.R1239C | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs771459439, COSV56535393, COSV99813147; called by muse, mutect2, varscan2
- DPP10 | c.1999C>A p.L667I | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV59677327; called by muse, mutect2, varscan2
- DPP9 | c.1148del p.P383Rfs*15 (on ENST00000598800; = p.P412Rfs*15 on NM_139159.5) | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs747759328, COSV53593143; called by mutect2, varscan2
- DPY19L2P2 | n.683G>A | Splice Region (SNP) | VAF 30/244 reads (12%) | catalogued as rs369114642; called by muse, mutect2, varscan2
- DPY19L4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.711); catalogued as rs773985243, COSV68962345; called by muse, mutect2, varscan2
- DRAXIN | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as rs1040519549, COSV53845025; called by muse, mutect2, varscan2
- DSE | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 40/416 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs755108093, COSV59063491; called by muse, mutect2
- DUOX1 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs150434930, COSV58481184; called by muse, mutect2, varscan2
- DUS2 | c.554+1G>A p.X185_splice | Splice Site (SNP) | VAF 27/122 reads (22%) | catalogued as rs1352641626; called by muse, mutect2, varscan2
- DUS3L | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57831096; called by muse, varscan2
- DYRK1B | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 5/7 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as rs893357514; called by mutect2, varscan2
- EBI3 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs546327021, COSV55691625; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs754312859, COSV62567475; called by mutect2, varscan2
- EFCAB7 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 75/308 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as COSV64314767; called by muse, mutect2, varscan2
- EHD4 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1220202517; called by muse, mutect2, varscan2
- EIF3J | c.89dup p.G31Rfs*21 | Frame Shift Ins (INS) | VAF 16/91 reads (18%) | catalogued as rs1195135491; called by mutect2, pindel, varscan2
- EIF4G3 | c.3458G>A p.R1153K | Missense Mutation (SNP) | VAF 70/286 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.779); catalogued as rs1333608090; called by muse, mutect2, varscan2
- EIF5B | c.149del p.K50Sfs*10 | Frame Shift Del (DEL) | VAF 64/244 reads (26%) | catalogued as rs749961066, COSV56813566; called by mutect2, varscan2
- ELN | c.163+2T>A p.X55_splice | Splice Site (SNP) | VAF 32/161 reads (20%) | catalogued as CS101100, COSV52706956, COSV99333224; called by muse, mutect2, varscan2
- ELP3 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.086); catalogued as COSV99833702; called by muse, mutect2, varscan2
- ENC1 | c.1582C>T p.R528C | Missense Mutation (SNP) | VAF 84/382 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as COSV100188234; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | catalogued as rs761717176; called by mutect2, varscan2
- EP400 | c.5035G>A p.A1679T | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs1462373184; called by muse, mutect2, varscan2
- EPHX1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 34/476 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1456389783; called by muse, mutect2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- EPS8L2 | c.112_114del p.K38del | In Frame Del (DEL) | VAF 19/107 reads (18%) | catalogued as rs1306252573; called by pindel, varscan2
- ERCC6L | c.2410G>T p.G804C | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100559058; called by muse, mutect2
- ERN2 | c.2306G>A p.R769H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776933345; called by muse, mutect2, varscan2
- ESPNL | c.823del p.L275Sfs*16 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs1309653898; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | catalogued as rs775950025; called by mutect2, varscan2
- ESX1 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs782128803, COSV65424542; called by muse, mutect2, varscan2
- ESYT3 | c.1892del p.P631Qfs*60 | Frame Shift Del (DEL) | VAF 43/222 reads (19%) | catalogued as COSV67441023; called by mutect2, pindel, varscan2
- ETNK2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1032199748; called by muse, mutect2, varscan2
- EXD3 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1420308836, COSV59809238; called by muse, mutect2, varscan2
- F2R | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as rs777334197, COSV59930250; called by muse, mutect2, varscan2
- F8 | c.3870del p.E1292Rfs*16 | Frame Shift Del (DEL) | VAF 57/491 reads (12%) | catalogued as rs1426645898, CD022147, CD0911173, COSV64270790; called by mutect2, pindel, varscan2
- FAHD2A | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1166763256; called by muse, mutect2, varscan2
- FAM120B | c.892dup p.Y298Lfs*2 | Frame Shift Ins (INS) | VAF 83/390 reads (21%) | catalogued as rs776399101; called by mutect2, pindel, varscan2
- FAM160A2 | c.1079G>A p.S360N | Missense Mutation (SNP) | VAF 34/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1183714732; called by muse, mutect2, varscan2
- FAM163A | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs138488792; called by muse, mutect2, varscan2
- FAM217A | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 32/356 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs564746939; called by muse, mutect2
- FAM219A | c.169C>T p.R57W (on ENST00000445726; = p.R40W on NM_147202.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs573238825; called by muse, mutect2, varscan2
- FAM234B | c.1190G>A p.C397Y | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT tolerated (1); PolyPhen possibly damaging (0.629); catalogued as COSV52194178; called by muse, mutect2, varscan2
- FAM27E5 | n.277G>A | Splice Region (SNP) | VAF 13/82 reads (16%) | catalogued as rs764075766; called by muse, mutect2, varscan2
- FANCE | c.929dup p.V311Sfs*2 | Frame Shift Ins (INS) | VAF 116/392 reads (30%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, varscan2
- FAS | c.403del p.C135Vfs*52 | Frame Shift Del (DEL) | VAF 136/347 reads (39%) | catalogued as rs1564692984, CX113055, COSV58238368; called by mutect2, varscan2
- FAT1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 54/266 reads (20%) | catalogued as COSV71672617; called by muse, mutect2, varscan2
- FBN3 | c.1803del p.L602Wfs*3 | Frame Shift Del (DEL) | VAF 15/86 reads (17%) | catalogued as rs772353703; called by mutect2, pindel, varscan2
- FBXL7 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61649228; called by muse, varscan2
- FCN3 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372707264; called by muse, mutect2, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 32/130 reads (25%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGF22 | c.448del p.R150Gfs*75 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as rs760109035, COSV51260890; called by mutect2, pindel, varscan2
- FGFRL1 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs770052916, COSV53256635; called by muse, varscan2
- FHOD1 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 48/158 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs139223474; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | catalogued as rs769482947; called by mutect2, varscan2
- FOXF1 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99296512; called by muse, mutect2, varscan2
- FOXL3 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1364470795, COSV101546371; called by muse, mutect2, varscan2
- FRY | c.4349A>G p.N1450S | Missense Mutation (SNP) | VAF 91/416 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as rs1413212732; called by muse, mutect2, varscan2
- FRZB | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.17); catalogued as COSV54555586; called by muse, mutect2, varscan2
- FUBP3 | c.1401G>T p.K467N | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60513480; called by muse, mutect2, varscan2
- FZD4 | c.929A>G p.Y310C | Missense Mutation (SNP) | VAF 79/760 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777030284; called by muse, mutect2, varscan2
- G2E3 | c.1916G>A p.C639Y | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs765789146; called by muse, mutect2
- GAB3 | c.259A>G p.I87V | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.89); PolyPhen benign (0.114); catalogued as rs782388455; called by muse, mutect2, varscan2
- GALC | c.1972T>C p.F658L | Missense Mutation (SNP) | VAF 87/459 reads (19%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV54326503; called by muse, mutect2, varscan2
- GALNT12 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 73/359 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs780195786, COSV66662302; ClinVar: likely benign; called by muse, mutect2, varscan2
- GARRE1 | c.160dup p.L54Pfs*85 | Frame Shift Ins (INS) | VAF 23/109 reads (21%) | catalogued as rs1246327376; called by mutect2, pindel, varscan2
- GARRE1 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 22/223 reads (10%) | catalogued as COSV55103390; called by muse, mutect2, varscan2
- GCC1 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as COSV99133842, COSV99133943; called by muse, mutect2, varscan2
- GGT7 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs1200266687; called by muse, mutect2, varscan2
- GIP | c.85A>G p.S29G | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.14); catalogued as rs746626277; called by muse, mutect2, varscan2
- GJA1 | c.330G>T p.E110D | Missense Mutation (SNP) | VAF 85/382 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.142); catalogued as CM055276; called by muse, mutect2, varscan2
- GJC2 | c.81G>A p.W27* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as rs1180319605, COSV64513063; called by muse, mutect2, varscan2
- GLI2 | c.1615C>T p.R539C (on ENST00000361492 / NM_001374353.1; = p.R556C on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58034512, COSV58039499; called by muse, mutect2, varscan2
- GLI3 | c.4447G>T p.G1483C | Missense Mutation (SNP) | VAF 99/514 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67886518; called by muse, mutect2, varscan2
- GLRA4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as rs760985980, COSV60327251, COSV60328111; called by muse, mutect2, varscan2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 22/72 reads (31%) | catalogued as rs749150409; called by mutect2, varscan2
- GMCL1 | c.842del p.K281Sfs*15 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as rs1558541290; called by mutect2, pindel, varscan2
- GNAL | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV61850385; called by muse, mutect2, varscan2
- GOLGA6C | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 78/381 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as rs1445171676; called by muse, mutect2, varscan2
- GP2 | c.1570T>C p.W524R (on ENST00000381362 / NM_001007240.3; = p.W521R on NM_001502.4) | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1344467442; called by muse, mutect2, varscan2
- GPBP1L1 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV51974124; called by muse, mutect2
- GPC2 | c.1047del p.D350Tfs*24 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as rs748011069, COSV52786506; called by pindel, varscan2
- GPHN | c.1314+3A>G | Splice Region (SNP) | VAF 61/267 reads (23%) | catalogued as rs745860575; called by muse, mutect2, varscan2
- GPI | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.748); catalogued as rs769204005; called by muse, mutect2, varscan2
- GREB1 | c.5366C>T p.A1789V | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.209); catalogued as rs369673905, COSV99303719; called by muse, mutect2, varscan2
- GRIA1 | c.2088del p.F696Lfs*9 | Frame Shift Del (DEL) | VAF 33/177 reads (19%) | catalogued as COSV53587507; called by mutect2, pindel, varscan2
- GRIA3 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 100/417 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1237670620, COSV52079719; called by muse, mutect2, varscan2
- GRK5 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs375507983, COSV100963092; called by muse, mutect2, varscan2
- GRM1 | c.3148G>A p.A1050T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV51121869; called by mutect2, varscan2
- GRM7 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100736158; called by mutect2, varscan2
- GRM7 | c.2427del p.F809Lfs*21 | Frame Shift Del (DEL) | VAF 22/50 reads (44%) | catalogued as rs747773579; called by mutect2, varscan2
- GRM8 | c.1194G>T p.Q398H | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV58824093; called by muse, mutect2, varscan2
- GRWD1 | c.673dup p.R225Pfs*10 | Frame Shift Ins (INS) | VAF 14/144 reads (10%) | catalogued as rs770573431; called by mutect2, pindel
- GTF2IRD1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs373085188; called by muse, mutect2, varscan2
- GTPBP3 | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1205911582; called by muse, mutect2, varscan2
- GUCY1B1 | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477623895, COSV52378347; called by muse, mutect2, varscan2
- H2BC4 | c.310C>A p.P104T | Missense Mutation (SNP) | VAF 69/377 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV58417118; called by muse, mutect2, varscan2
- HCCS | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 63/263 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372501217, COSV58239558; called by muse, mutect2, varscan2
- HCFC1 | c.4418C>T p.T1473M | Missense Mutation (SNP) | VAF 33/164 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs201219961, COSV60069930; called by muse, mutect2, varscan2
- HDAC9 | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs546754813, COSV67769159; called by muse, mutect2, varscan2
- HECTD3 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as rs1237494697; called by muse, mutect2, varscan2
- HEPH | c.1568del p.P523Lfs*24 (on ENST00000343002; = p.P256Lfs*24 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/188 reads (21%) | catalogued as COSV100294364, COSV57958868; called by mutect2, varscan2
- HFM1 | c.4200del p.F1400Lfs*25 | Frame Shift Del (DEL) | VAF 35/301 reads (12%) | catalogued as rs766204131; called by mutect2, pindel, varscan2
- HHLA1 | c.994G>A p.V332M | Missense Mutation (SNP) | VAF 62/275 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs118152489; called by muse, mutect2, varscan2
- HIVEP2 | c.5745T>A p.D1915E | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1305067476, COSV50005601; called by mutect2, varscan2
- HK3 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs146374391, COSV99458034; called by muse, mutect2, varscan2
- HMCN1 | c.3785C>A p.P1262H | Missense Mutation (SNP) | VAF 54/316 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54901334; called by mutect2, varscan2
- HMCN1 | c.11440A>G p.T3814A | Missense Mutation (SNP) | VAF 36/508 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as rs1421603002; called by muse, mutect2
- HMGCR | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1430662318, COSV55316673; called by muse, mutect2, varscan2
- HMOX1 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 69/323 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1414251328; called by muse, mutect2, varscan2
- HOXA13 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs761927877; called by muse, mutect2, varscan2
- HRAS | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 55/246 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.624); catalogued as rs749674880, COSV54241667; called by muse, mutect2, varscan2
- HTR1A | c.758G>A p.S253N | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs147211774, COSV60501213; called by muse, mutect2, varscan2
- HTR1A | c.451del p.R151Gfs*104 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as COSV60500604; called by mutect2, pindel, varscan2
- HTR3E | c.919del p.L307Sfs*12 (on ENST00000415389 / NM_001256613.1; = p.L322Sfs*12 on NM_182589.2) | Frame Shift Del (DEL) | VAF 27/203 reads (13%) | catalogued as rs754509192; called by mutect2, pindel, varscan2
- HYAL4 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as rs1207198202; called by muse, mutect2, varscan2
- IBTK | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370183816, COSV60395545; called by muse, mutect2, varscan2
- IDE | c.1152A>G p.L384= | Splice Region (SNP) | VAF 31/162 reads (19%) | catalogued as rs955861956; called by muse, mutect2, varscan2
- IGHV3-20 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.037); catalogued as rs782449916; called by muse, mutect2, varscan2
- IGHV3-48 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.196); catalogued as rs560104138; called by muse, varscan2
- IL17REL | c.213del p.Q72Sfs*12 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs747097955, COSV58008141; called by pindel, varscan2
- IL18R1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs773036985, COSV52126307, COSV99295001; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as rs760925109; called by mutect2, varscan2
- INSM2 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 31/164 reads (19%) | catalogued as rs112231564, COSV99355317; called by muse, mutect2, varscan2
- IQSEC3 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 22/117 reads (19%) | catalogued as rs1555083306; called by muse, mutect2, varscan2
- IRX1 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100116101; called by muse, mutect2, varscan2
- IRX6 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1411214050; called by muse, varscan2
- ISLR2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178197724; called by muse, mutect2, varscan2
- ISM1 | c.579del p.R194Gfs*82 | Frame Shift Del (DEL) | VAF 28/178 reads (16%) | catalogued as rs762230866, COSV99339624; called by pindel, varscan2
- ITGB2 | c.1474G>T p.G492C (on ENST00000302347; = p.G468C on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100186199; called by muse, mutect2, varscan2
- ITPR2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200176064; called by muse, mutect2, varscan2
- ITSN1 | c.4705G>A p.A1569T | Missense Mutation (SNP) | VAF 24/200 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67157443; called by muse, mutect2, varscan2
- JPH1 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.179); catalogued as rs376014048, COSV60609890; called by muse, mutect2, varscan2
- JRK | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200789015; called by muse, mutect2, varscan2
- KCMF1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 67/277 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs1426886983, COSV69054356; called by muse, mutect2, varscan2
- KCNC3 | c.1880del p.G627Efs*27 | Frame Shift Del (DEL) | VAF 6/57 reads (11%) | catalogued as rs1159900432; called by pindel, varscan2
- KCNE4 | c.397del p.E133Rfs*3 | Frame Shift Del (DEL) | VAF 20/139 reads (14%) | catalogued as rs760505003; called by mutect2, varscan2
- KCNH4 | c.1564G>A p.V522I | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs751569305, COSV52920746; called by muse, varscan2
- KCNJ14 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs750940601, COSV60738346, COSV60738731; called by muse, mutect2, varscan2
- KCNS2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.207); catalogued as rs911026515, COSV54638856; called by muse, mutect2, varscan2
- KCNT2 | c.2525C>T p.P842L | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as COSV54085404; called by muse, mutect2, varscan2
- KCNT2 | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54072982; called by muse, varscan2
- KDM5A | c.4517G>A p.R1506Q | Missense Mutation (SNP) | VAF 70/271 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs1406794971; called by muse, mutect2, varscan2
- KDM5C | c.3563G>C p.C1188S | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64767622; called by muse, mutect2, varscan2
- KIAA1614 | c.149del p.P50Qfs*15 | Frame Shift Del (DEL) | VAF 15/55 reads (27%) | catalogued as rs771572430; called by mutect2, pindel, varscan2
- KIF18A | c.587A>G p.Q196R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.292); catalogued as COSV99589153; called by muse, mutect2, varscan2
- KIN | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.994); catalogued as rs751941059; called by muse, mutect2, varscan2
- KIR3DL1 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs757344213; called by muse, mutect2, varscan2
- KLF15 | c.1243G>A p.V415M | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs983434622, COSV56179511; called by muse, mutect2, varscan2
- KLHL2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as COSV56976636; called by muse, mutect2, varscan2
- KLRD1 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 66/342 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs201683513, COSV60273294; called by muse, mutect2, varscan2
- KMT2B | c.3145del p.A1049Rfs*133 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as COSV55869560; called by pindel, varscan2
- KMT2B | c.3347C>T p.P1116L | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs759860714; called by muse, mutect2, varscan2
- KRIT1 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 100/531 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs569494969, COSV60669252; called by muse, mutect2, varscan2
- KRT16 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 51/210 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs1324353859; called by muse, mutect2, varscan2
- KRTAP10-7 | c.97C>T p.Q33* | Nonsense Mutation (SNP) | VAF 42/230 reads (18%) | catalogued as rs1555928376; called by muse, mutect2, varscan2
- KRTAP5-1 | c.263del p.G88Afs*? | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs1554942480, COSV101192918; called by mutect2, pindel, varscan2
- KTI12 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs769787346; called by muse, mutect2, varscan2
- L3HYPDH | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371673690; called by muse, mutect2, varscan2
- LARGE2 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs867397092, COSV57656368; called by muse, mutect2, varscan2
- LDLRAP1 | c.604del p.S202Pfs*2 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | catalogued as COSV65473126, COSV65473260; called by mutect2, pindel, varscan2
- LENG8 | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs200163681, COSV100457043; called by muse, mutect2, varscan2
- LHCGR | c.1916G>A p.S639N | Missense Mutation (SNP) | VAF 94/477 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.244); catalogued as rs149766676; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 22/113 reads (19%) | catalogued as rs775423572; called by mutect2, varscan2
- LILRB4 | c.337del p.L113Wfs*4 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | catalogued as rs1044045850; called by mutect2, pindel, varscan2
- LINGO3 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.142); catalogued as COSV68261605; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 38/183 reads (21%) | catalogued as rs780042765; called by mutect2, varscan2
- LOXL3 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs865846469, COSV51209998, COSV51213355; called by muse, mutect2, varscan2
- LPAR4 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472738201, COSV70912902; called by muse, mutect2, varscan2
- LPIN1 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs199755819, COSV56762562; called by muse, mutect2, varscan2
- LRIT2 | c.1337T>C p.V446A | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as rs770528831; called by muse, mutect2, varscan2
- LRP2 | c.6289G>A p.A2097T | Missense Mutation (SNP) | VAF 84/410 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.546); catalogued as rs537120899, COSV55569310; called by muse, mutect2, varscan2
- LRRC14B | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774735073, COSV52043157; called by muse, mutect2, varscan2
- LRRN3 | c.1156A>G p.I386V | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs770099594; called by muse, mutect2, varscan2
- LTBP1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs779332816, COSV100617225; called by muse, mutect2, varscan2
- LTBP2 | c.709C>T p.R237* | Nonsense Mutation (SNP) | VAF 39/438 reads (9%) | catalogued as rs1216378691; called by muse, mutect2
- LTN1 | c.5123G>A p.R1708H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs1179534755, COSV63732905; called by muse, mutect2, varscan2
- LVRN | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.838); catalogued as COSV63496963; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.260G>T p.G87V | Missense Mutation (SNP) | VAF 54/365 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65443190; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV65442901; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 5/42 reads (12%) | catalogued as rs1159257962; called by mutect2, pindel
- MAMDC4 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201981906; called by muse, mutect2, varscan2
- MAP2K3 | c.124del p.R42Gfs*24 (on ENST00000342679 / NM_145109.3; = p.R13Gfs*24 on NM_002756.4) | Frame Shift Del (DEL) | VAF 20/176 reads (11%) | catalogued as rs1567665648, COSV57561353; called by pindel, varscan2
- MAP3K9 | c.2408G>A p.R803H (on ENST00000554752 / NM_001284230.1; = p.R817H on NM_033141.4) | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs756820633, COSV101173491; called by muse, mutect2, varscan2
- MAP4K3 | c.569del p.G190Vfs*16 | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | catalogued as rs1451169538; called by mutect2, pindel, varscan2
- MAP7D1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1322612960; called by muse, mutect2, varscan2
- MAP7D1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1483034661; called by muse, mutect2, varscan2
- MAPT | c.769C>T p.R257C (on ENST00000262410 / NM_001377265.1; = p.R182C on NM_016835.4) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.045); catalogued as rs763093275, COSV52242390; ClinVar: likely benign; called by muse, mutect2, varscan2
- MATN4 | c.668dup p.H224Tfs*28 | Frame Shift Ins (INS) | VAF 29/113 reads (26%) | catalogued as rs1568878182; called by mutect2, pindel, varscan2
- MCM2 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs144869999; called by muse, mutect2, varscan2
- MCTP2 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 41/170 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.706); catalogued as rs1164277510; called by muse, mutect2, varscan2
- MED12 | c.5464C>T p.H1822Y | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.932); catalogued as COSV100376752, COSV61335340; called by muse, mutect2
- MED12 | c.5696G>A p.R1899Q | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT tolerated, low confidence (0.6); PolyPhen possibly damaging (0.489); catalogued as rs867804014, COSV61330344; called by muse, mutect2, varscan2
- MFN2 | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 76/264 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV52423441; called by muse, mutect2, varscan2
- MFSD10 | c.1147G>A p.V383M | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as rs940132085; called by muse, mutect2, varscan2
- MGAT1 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 22/108 reads (20%) | PolyPhen probably damaging (0.97); catalogued as rs375119923; called by muse, varscan2
- MGAT1 | c.443C>T p.T148M | Missense Mutation (SNP) | VAF 26/115 reads (23%) | PolyPhen probably damaging (0.999); catalogued as COSV57133014; called by muse, varscan2
- MICAL3 | c.4495del p.R1499Gfs*106 | Frame Shift Del (DEL) | VAF 21/96 reads (22%) | catalogued as rs765803753; called by mutect2, varscan2
- MID2 | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 46/214 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs190213818; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs762448666; called by mutect2, pindel
- MIDN | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs1423452435; called by muse, mutect2, varscan2
- MIIP | c.901C>T p.R301* | Nonsense Mutation (SNP) | VAF 20/171 reads (12%) | catalogued as rs143903150; called by muse, mutect2, varscan2
- MKNK2 | c.51+2T>C p.X17_splice | Splice Site (SNP) | VAF 30/143 reads (21%) | catalogued as rs746335974; called by muse, mutect2, varscan2
- MMP16 | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs760308984, COSV54151216; called by muse, mutect2, varscan2
- MN1 | c.3299del p.P1100Rfs*78 | Frame Shift Del (DEL) | VAF 32/131 reads (24%) | catalogued as COSV100180020; called by mutect2, pindel, varscan2
- MOS | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1421842842, COSV61336285; called by muse, mutect2
- MPDZ | c.1197del p.K399Nfs*9 | Frame Shift Del (DEL) | VAF 48/240 reads (20%) | catalogued as COSV100060635; called by mutect2, varscan2
- MPL | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs756918176, COSV65247589; called by muse, mutect2, varscan2
- MRGPRF | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as rs1007221994; called by muse, mutect2, varscan2
- MRTFB | c.2650del p.R884Afs*44 (on ENST00000571589 / NM_001365412.2; = p.R834Afs*44 on NM_014048.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | catalogued as rs768684761; called by mutect2, pindel, varscan2
- MSL2 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 92/457 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53869865; called by muse, mutect2, varscan2
- MSLNL | c.1921del p.L641Wfs*49 | Frame Shift Del (DEL) | VAF 33/130 reads (25%) | catalogued as rs1162250648; called by mutect2, pindel, varscan2
- MSLNL | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs376078479; called by muse, mutect2, varscan2
- MSN | c.1002G>T p.E334D | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV64303140; called by muse, mutect2, varscan2
- MTREX | c.1251del p.K418Rfs*24 | Frame Shift Del (DEL) | VAF 46/185 reads (25%) | catalogued as rs1445650082; called by mutect2, pindel, varscan2
- MTRF1L | c.260-6del | Splice Region (DEL) | VAF 39/182 reads (21%) | catalogued as rs750386363; called by mutect2, pindel, varscan2
- MUC12 | c.9338A>G p.H3113R (on ENST00000379442; = p.H2970R on NM_001164462.1) | Missense Mutation (SNP) | VAF 22/518 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs1190715775; called by muse, mutect2
- MUC16 | c.31853del p.F10618Sfs*5 | Frame Shift Del (DEL) | VAF 25/129 reads (19%) | catalogued as COSV67478250; called by mutect2, pindel, varscan2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 34/121 reads (28%) | catalogued as rs537060918; called by mutect2, varscan2
- MUSK | c.846C>A p.C282* | Nonsense Mutation (SNP) | VAF 43/180 reads (24%) | catalogued as rs762707937; called by muse, mutect2, varscan2
- MVP | c.2221G>A p.V741M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1478942622, COSV62422979; called by muse, mutect2, varscan2
- MXRA5 | c.1327C>T p.R443* | Nonsense Mutation (SNP) | VAF 61/249 reads (24%) | catalogued as COSV54245869; called by muse, mutect2, varscan2
- MYO16 | c.2909C>A p.S970Y | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV51823131; called by muse, mutect2, varscan2
- MYO16 | c.4423G>A p.A1475T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs760176567; called by muse, varscan2
- MYO6 | c.2161T>C p.Y721H | Missense Mutation (SNP) | VAF 114/579 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as rs745934653; called by muse, mutect2, varscan2
- MYO9B | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 77/305 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1243580202, COSV68282767; called by muse, mutect2, varscan2
- MYO9B | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as rs1192927828; called by muse, mutect2, varscan2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 58/146 reads (40%) | catalogued as rs763929397; called by mutect2, varscan2
- NANOS1 | c.822del p.A275Pfs*76 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as rs1490227868; called by mutect2, varscan2
- NAPEPLD | c.842del p.F281Sfs*14 | Frame Shift Del (DEL) | VAF 44/182 reads (24%) | catalogued as rs746683932, COSV100439928; called by mutect2, varscan2
- NAV2 | c.839+2T>C p.X280_splice | Splice Site (SNP) | VAF 38/164 reads (23%) | catalogued as COSV62329132; called by muse, mutect2, varscan2
- NAV3 | c.2132+8del p.X711_splice | Splice Site (DEL) | VAF 16/141 reads (11%) | catalogued as rs762130643, COSV99897039; called by mutect2, pindel, varscan2
- NAV3 | c.6683dup p.L2228Ffs*8 (on ENST00000397909 / NM_001024383.2; = p.L2206Ffs*8 on NM_014903.6) | Frame Shift Ins (INS) | VAF 18/198 reads (9%) | catalogued as rs754347582; called by mutect2, pindel
- NBPF9 | c.490C>T p.P164S | Missense Mutation (SNP) | VAF 19/386 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs782709007; called by muse, mutect2
- NDUFC2 | c.207del p.F69Lfs*7 | Frame Shift Del (DEL) | VAF 30/122 reads (25%) | catalogued as rs747914168; called by mutect2, varscan2
- NDUFS1 | c.610A>G p.M204V | Missense Mutation (SNP) | VAF 103/381 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1192554517, COSV51911222; called by muse, mutect2, varscan2
- NDUFV3 | c.242C>T p.T81M (on ENST00000340344 / NM_001001503.2; = p.T446M on NM_021075.4) | Missense Mutation (SNP) | VAF 81/369 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs145389563; called by muse, mutect2, varscan2
- NECTIN4 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs763563412; called by muse, mutect2, varscan2
- NEDD1 | c.733T>G p.L245V | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1247602123; called by muse, mutect2, varscan2
- NEK9 | c.1262A>G p.E421G | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1308237172; called by muse, mutect2
- NEMP2 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as rs766276124; called by muse, mutect2, varscan2
- NFATC2 | c.1460C>G p.T487S | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.794); catalogued as rs772516112, COSV101044845, COSV65355027; called by muse, mutect2, varscan2
- NID2 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV53499087; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 32/136 reads (24%) | catalogued as rs145147241; called by mutect2, varscan2
- NISCH | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs202168458; called by muse, mutect2, varscan2
- NKAP | c.76A>G p.K26E | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as COSV101004234; called by muse, mutect2, varscan2
- NLRP12 | c.2188del p.V730* | Frame Shift Del (DEL) | VAF 44/189 reads (23%) | catalogued as rs771632319; called by mutect2, pindel, varscan2
- NONO | c.84C>G p.H28Q | Missense Mutation (SNP) | VAF 42/218 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs755849952; called by muse, mutect2, varscan2
- NOS1 | c.2027dup p.C677Lfs*38 | Frame Shift Ins (INS) | VAF 20/101 reads (20%) | catalogued as rs746543323; called by mutect2, varscan2
- NOS3 | c.1319del p.G440Afs*64 | Frame Shift Del (DEL) | VAF 20/84 reads (24%) | catalogued as rs749517498, COSV52496454; called by mutect2, pindel, varscan2
- NPAS3 | c.1084G>A p.V362I (on ENST00000356141 / NM_001164749.2; = p.V330I on NM_022123.3) | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.049); catalogued as rs184170938; called by muse, mutect2, varscan2
- NPY1R | c.890A>G p.N297S | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs764292344; called by muse, mutect2, varscan2
- NR2C2 | c.1689del p.F563Lfs*10 (on ENST00000393102; = p.F582Lfs*10 on NM_003298.5) | Frame Shift Del (DEL) | VAF 36/134 reads (27%) | catalogued as rs774343392; called by mutect2, varscan2
- NR2F6 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs909784828, COSV52242975; called by muse, mutect2, varscan2
- NR4A1 | c.1628C>T p.A543V | Missense Mutation (SNP) | VAF 40/221 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs764768496; called by muse, mutect2, varscan2
- NRDC | c.2520A>G p.L840= | Splice Region (SNP) | VAF 28/118 reads (24%) | catalogued as rs543806117, COSV61405190; called by muse, mutect2, varscan2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 22/184 reads (12%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs747948664; called by muse, mutect2, varscan2
- NRXN1 | c.3706C>T p.R1236C | Missense Mutation (SNP) | VAF 64/278 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV60508639; called by muse, mutect2, varscan2
- NRXN3 | c.1898C>T p.A633V (on ENST00000335750 / NM_001330195.2; = p.A260V on NM_004796.6) | Missense Mutation (SNP) | VAF 48/275 reads (17%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.992); catalogued as rs1385599857, COSV59723317; called by muse, mutect2, varscan2
- NTN3 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.908); catalogued as rs1008935877, COSV53548341; called by muse, varscan2
- NTSR2 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV60991595; called by muse, mutect2, varscan2
- NUP85 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 42/184 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373568508, COSV99823019; called by muse, mutect2, varscan2
- NWD1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.537); catalogued as rs755237671, COSV60342348; called by muse, mutect2, varscan2
- NWD1 | c.3292C>A p.L1098I | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.133); catalogued as rs1046605418; called by muse, mutect2, varscan2
- NWD2 | c.83C>T p.T28M | Missense Mutation (SNP) | VAF 49/250 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.088); catalogued as rs778643721, COSV58751379; called by muse, mutect2, varscan2
- OBSCN | c.12664G>A p.V4222M | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs375322738; called by muse, mutect2, varscan2
- OBSCN | c.20353G>A p.D6785N | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs758690906; called by muse, varscan2
- OPN5 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1287837880; called by muse, mutect2, varscan2
- OR10G7 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs746205816; called by muse, mutect2, varscan2
- OR10K1 | c.242T>C p.M81T | Missense Mutation (SNP) | VAF 76/357 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs778443144; called by muse, mutect2, varscan2
- OR10Z1 | c.265del p.D89Tfs*48 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | catalogued as rs752054889; called by mutect2, pindel, varscan2
- OR2C3 | c.658G>A p.G220S | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776976495, COSV63576171; called by muse, mutect2, varscan2
- OR2L5 | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as COSV62365008; called by muse, mutect2, varscan2
- OR2M3 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71759068; called by muse, mutect2, varscan2
- OR2T3 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV62083094; called by muse, mutect2, varscan2
- OR2Z1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs782781680; called by muse, mutect2, varscan2
- OR4C6 | c.180del p.T62Pfs*18 | Frame Shift Del (DEL) | VAF 16/178 reads (9%) | catalogued as rs781182602; called by mutect2, pindel
- OR4D6 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764578155, COSV55660383, COSV55660812; called by muse, mutect2, varscan2
- OR5AC2 | c.860T>C p.L287P | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs1386820434; called by muse, mutect2, varscan2
- OSBP | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55665184; called by muse, mutect2
- OXLD1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs536616884; called by muse, mutect2, varscan2
- PALM3 | c.1254G>T p.E418D (on ENST00000340790; = p.E433D on NM_001145028.2) | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.031); catalogued as COSV54602702; called by muse, mutect2, varscan2
- PAPPA | c.4078G>A p.A1360T | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs539350327, COSV60277984; called by muse, mutect2, varscan2
- PARD6A | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs956756724; called by muse, mutect2, varscan2
- PCDH7 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100688462; called by muse, mutect2, varscan2
- PCDH8 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs374758530; called by muse, mutect2, varscan2
- PCDHA12 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 87/347 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV56476669; called by muse, mutect2, varscan2
- PCDHB6 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.686); catalogued as rs781917011, COSV50695777; called by muse, mutect2, varscan2
- PCDHB8 | c.2051C>T p.A684V | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); catalogued as rs369925528; called by muse, mutect2, varscan2
- PCDHGA1 | c.2191G>A p.G731S | Missense Mutation (SNP) | VAF 85/443 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as rs568434037, COSV65295578; called by muse, mutect2, varscan2
- PCDHGC3 | c.2066del p.N689Ifs*10 | Frame Shift Del (DEL) | VAF 37/172 reads (22%) | catalogued as rs1156842877; called by mutect2, varscan2
- PCGF1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1177968467, COSV99283141; called by muse, mutect2, varscan2
- PCSK1 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 23/300 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60734579; called by muse, mutect2
- PCYOX1 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52478492; called by muse, varscan2
- PCYT1B | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.198); catalogued as rs202170430; called by muse, mutect2, varscan2
- PDCD11 | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs369125073; called by muse, mutect2, varscan2
- PDE4A | c.1241C>T p.T414M (on ENST00000380702 / NM_001111307.2; = p.T175M on NM_006202.3) | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs777046337; called by muse, mutect2, varscan2
- PDE4DIP | c.4308G>T p.K1436N | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs781881123; called by muse, mutect2
- PDHA2 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as rs747424149, COSV54781055, COSV99756891; called by muse, varscan2
- PDIA2 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs770165640, COSV51986214, COSV51988242; called by muse, mutect2, varscan2
- PDK4 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 7/132 reads (5%) | catalogued as rs1354374215; called by muse, mutect2
- PDZD7 | c.2695G>A p.A899T | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs911911177; called by muse, mutect2
- PGM5 | c.1255C>T p.R419* | Nonsense Mutation (SNP) | VAF 25/111 reads (23%) | catalogued as rs782413315, COSV101123813, COSV67169381; called by muse, mutect2, varscan2
- PGR | c.857A>G p.D286G | Missense Mutation (SNP) | VAF 70/407 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV99678729; called by muse, varscan2
- PHF1 | c.1144G>A p.G382R (on ENST00000374516 / NM_024165.3; = p.G378E on NM_002636.5) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.996); catalogued as rs757078823; called by muse, mutect2, varscan2
- PHF14 | c.1618C>T p.R540W | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs747272623, COSV68857716; called by muse, mutect2, varscan2
- PIEZO1 | c.3208C>T p.R1070C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1209538803; called by muse, mutect2, varscan2
- PIEZO2 | c.5636C>T p.T1879M | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs1046341047; called by muse, mutect2, varscan2
- PIGO | c.1361del p.G454Vfs*31 | Frame Shift Del (DEL) | VAF 90/242 reads (37%) | catalogued as COSV53054111, COSV53054694; called by mutect2, pindel, varscan2
- PIK3C3 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56278298; called by muse, mutect2
- PIK3CB | c.3076-1G>A p.X1026_splice | Splice Site (SNP) | VAF 30/109 reads (28%) | catalogued as COSV56686859; called by muse, mutect2, varscan2
- PIP4K2C | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs760924346; called by muse, mutect2, varscan2
- PKN2 | c.232del p.S78Vfs*5 | Frame Shift Del (DEL) | VAF 67/330 reads (20%) | catalogued as rs1335792632, COSV60133695; called by mutect2, pindel, varscan2
- PLAG1 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs771690216, COSV100387903, COSV57609257; called by muse, mutect2, varscan2
- PLCD1 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 26/311 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.28); catalogued as rs766472434, COSV52189109; called by muse, mutect2
- PLCG1 | c.3826C>T p.R1276* (on ENST00000373271 / NM_182811.2; = p.R1277* on NM_002660.3) | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as rs1201052162, COSV54819027; called by muse, mutect2, varscan2
- PLEC | c.1978C>T p.R660C (on ENST00000322810 / NM_201380.4; = p.R550C on NM_000445.5) | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs1554718496, COSV59641941; called by muse, mutect2, varscan2
- PLEKHG1 | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as COSV62050965; called by muse, mutect2, varscan2
- PMF1-BGLAP | c.637C>T p.P213S | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1349485727; called by muse, mutect2, varscan2
- PNMA2 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1563367914, COSV72908536; called by muse, mutect2, varscan2
- POLL | c.1516T>C p.F506L | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV54577858; called by muse, mutect2, varscan2
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 11/53 reads (21%) | catalogued as rs745933237; called by mutect2, pindel, varscan2
- POLR1C | c.502+7A>G | Splice Region (SNP) | VAF 110/353 reads (31%) | catalogued as rs377163139; called by muse, mutect2, varscan2
- POLR2A | c.4474G>A p.G1492S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.073); catalogued as rs746511216; called by muse, mutect2, varscan2
- POLR3B | c.1685T>C p.M562T | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs1565895217; called by muse, mutect2, varscan2
- POSTN | c.446T>A p.I149N | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV65712499; called by muse, mutect2, varscan2
- POU2AF1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.066); catalogued as rs147874251; called by muse, mutect2, varscan2
- PPFIA1 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 28/220 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV54132402; called by muse, mutect2, varscan2
- PPIG | c.1311C>G p.D437E | Missense Mutation (SNP) | VAF 58/250 reads (23%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV53642658; called by muse, mutect2
- PPL | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770248656, COSV52171571; called by muse, mutect2
- PPP1R3G | c.202del p.Q68Rfs*73 | Frame Shift Del (DEL) | VAF 31/243 reads (13%) | catalogued as rs1428762292; called by mutect2, pindel, varscan2
- PRAMEF19 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 67/311 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs752845494; called by muse, mutect2, varscan2
- PRC1 | c.162G>T p.M54I | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV62697022; called by muse, mutect2, varscan2
- PRL | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs998847824; called by muse, mutect2, varscan2
- PRPS1 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 88/369 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.277); catalogued as rs769401404; called by muse, varscan2
- PRR30 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 54/180 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.045); catalogued as rs1280227604; called by muse, mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS23 | c.1021del p.S341Qfs*8 | Frame Shift Del (DEL) | VAF 37/229 reads (16%) | catalogued as rs1565351247; called by mutect2, pindel, varscan2
- PRSS54 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs149972398; called by muse, mutect2, varscan2
- PRSS56 | c.659dup p.A221Cfs*19 | Frame Shift Ins (INS) | VAF 9/58 reads (16%) | catalogued as rs1228117846; called by mutect2, pindel, varscan2
- PRUNE2 | c.7276G>A p.A2426T | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.549); catalogued as rs1420375805; called by muse, mutect2, varscan2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 13/106 reads (12%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTCRA | c.424+1del | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | catalogued as COSV58976649; called by pindel, varscan2
- PTER | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 79/358 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV54346793; called by muse, mutect2, varscan2
- PTGDR | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs201541398, COSV100035572, COSV60094230; called by muse, mutect2, varscan2
- PTGDR2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs771871405; called by mutect2, varscan2
- PTPN23 | c.3581_3584del p.V1194Gfs*25 | Frame Shift Del (DEL) | VAF 24/122 reads (20%) | catalogued as rs760750644; called by mutect2, varscan2
- PTPRG | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs1417328865; called by muse, mutect2, varscan2
- PTPRN2 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.092); catalogued as rs192850596; called by muse, mutect2, varscan2
- PWWP2B | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 64/299 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs971536848, COSV100535707; called by muse, mutect2, varscan2
- QRFPR | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1211975206; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | catalogued as COSV100234622; called by mutect2, varscan2
- RAB11FIP4 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs141120275; called by muse, mutect2, varscan2
- RAI1 | c.4666C>T p.R1556C | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs925201797, COSV99883694; called by muse, mutect2, varscan2
- RB1 | c.1814T>A p.M605K | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV99031777; called by muse, mutect2, varscan2
- RBM15 | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 46/210 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.173); catalogued as rs893054196; called by muse, mutect2, varscan2
- RBM15B | c.2529del p.S844Pfs*27 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs781825075; called by mutect2, pindel, varscan2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 20/116 reads (17%) | catalogued as rs762006287; called by mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 32/176 reads (18%) | catalogued as COSV56484832; called by mutect2, varscan2
- RBP3 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs370124984; called by muse, mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 27/176 reads (15%) | catalogued as COSV65365594; called by mutect2, pindel, varscan2
- RDH16 | c.832del p.R278Vfs*17 | Frame Shift Del (DEL) | VAF 41/249 reads (16%) | catalogued as rs755216247; called by mutect2, pindel, varscan2
- RDX | c.1412dup p.P472Sfs*16 | Frame Shift Ins (INS) | VAF 78/312 reads (25%) | catalogued as rs780998172; called by mutect2, varscan2
- RECQL | c.1631_1633del p.K544del | In Frame Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs749841294; called by pindel, varscan2
- REG3A | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV59409416, COSV59411603; called by muse, mutect2, varscan2
- RELL2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs1268867264, COSV51837302; called by muse, mutect2, varscan2
- REV1 | c.992C>T p.T331M | Missense Mutation (SNP) | VAF 60/297 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as rs772023742; called by muse, mutect2, varscan2
- RGS9 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 79/310 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs769963081, COSV99287775; called by muse, mutect2, varscan2
- RHBDF2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as rs766047144, COSV57421510; called by muse, mutect2, varscan2
- RIMBP3 | c.2759C>T p.A920V | Missense Mutation (SNP) | VAF 73/499 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.059); catalogued as rs759347578; called by muse, mutect2, varscan2
- RIMS1 | c.1273C>T p.P425S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1359849027; called by muse, mutect2, varscan2
- RIOX1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1218164185; called by muse, mutect2, varscan2
- RIPOR2 | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52424010; called by muse, mutect2, varscan2
- RLF | c.4255del p.Y1419Ifs*6 | Frame Shift Del (DEL) | VAF 22/250 reads (9%) | catalogued as COSV65652466; called by mutect2, pindel
- RNF31 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs771019988, COSV53760492; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 38/87 reads (44%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNMT | c.1180del p.T394Hfs*19 | Frame Shift Del (DEL) | VAF 29/184 reads (16%) | catalogued as rs1436309196; called by mutect2, pindel, varscan2
- ROBO3 | c.1261T>C p.Y421H | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as COSV101185146; called by muse, mutect2, varscan2
- ROCK1 | c.2612del p.N871Tfs*5 | Frame Shift Del (DEL) | VAF 58/318 reads (18%) | catalogued as COSV67695859; called by mutect2, pindel, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 48/182 reads (26%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPRM | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57989291; called by muse, mutect2, varscan2
- RPS6KA1 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs535204806, COSV65178162; called by muse, varscan2
- RPS6KA2 | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371650855, COSV55820571; called by muse, mutect2, varscan2
- RRP8 | c.171del p.S58Afs*4 | Frame Shift Del (DEL) | VAF 21/112 reads (19%) | catalogued as rs1564836940; called by mutect2, pindel, varscan2
- RSRP1 | c.844del p.S282Vfs*20 | Frame Shift Del (DEL) | VAF 28/236 reads (12%) | catalogued as rs754096516; called by mutect2, pindel, varscan2
- RTEL1 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.34); catalogued as COSV58894992; called by muse, mutect2, varscan2
- RTL5 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV101030311; called by muse, mutect2, varscan2
- RTP1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs772092594, COSV56618245; called by muse, mutect2, varscan2
- RUNX2 | c.1385del p.G462Efs*22 (on ENST00000371438; = p.G440Efs*22 on NM_001015051.3) | Frame Shift Del (DEL) | VAF 172/534 reads (32%) | catalogued as rs1561822364, COSV61840797; called by mutect2, pindel, varscan2
- RYR1 | c.8580dup p.D2861Rfs*3 | Frame Shift Ins (INS) | VAF 39/192 reads (20%) | catalogued as rs757481998; called by mutect2, pindel, varscan2
- SACM1L | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs762241153; called by muse, mutect2, varscan2
- SBF1 | c.3228dup p.S1077Qfs*11 | Frame Shift Ins (INS) | VAF 20/84 reads (24%) | catalogued as rs771002611; called by mutect2, varscan2
- SCAMP4 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as rs542238969; called by muse, mutect2, varscan2
- SCN11A | c.3857T>C p.I1286T | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs368772706; called by muse, mutect2, varscan2
- SCN8A | c.3379G>T p.D1127Y | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV61992632; called by muse, mutect2
- SCN9A | c.3734G>T p.W1245L (on ENST00000303354; = p.W1234L on NM_002977.3) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57614139; called by muse, mutect2
- SCYL2 | c.164del p.K55Sfs*16 | Frame Shift Del (DEL) | VAF 36/168 reads (21%) | catalogued as rs34958515; called by mutect2, pindel, varscan2
- SDK2 | c.4472C>T p.S1491L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as rs773011099; called by muse, mutect2, varscan2
- SEC16A | c.6646G>A p.A2216T | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535521645; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEC22A | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 54/214 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs150060632; called by muse, mutect2, varscan2
- SEC61B | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201273722; called by muse, mutect2, varscan2
- SEC63 | c.1596A>T p.L532F | Missense Mutation (SNP) | VAF 78/305 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs756336859, COSV64598351, COSV64602524; called by muse, mutect2, varscan2
- SEMA5B | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1425205106; called by muse, mutect2, varscan2
- SEMA7A | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1053216716; called by muse, mutect2, varscan2
- SERPINB10 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200550911; called by muse, mutect2
- SESTD1 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 17/84 reads (20%) | catalogued as COSV58930399; called by muse, mutect2, varscan2
- SETD2 | c.7136C>T p.P2379L | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs200186997, COSV57436484; called by muse, mutect2, varscan2
- SETX | c.5603C>T p.P1868L | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs370368422; called by mutect2, varscan2
- SGSM2 | c.1523G>A p.R508H (on ENST00000426855 / NM_001098509.2; = p.R553H on NM_014853.3) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs1000822704; called by muse, mutect2, varscan2
- SH3TC1 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.046); catalogued as rs150357246; called by muse, mutect2, varscan2
- SHISA3 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV59980168; called by muse, mutect2
- SHOC1 | c.4333del p.*1445Efs*45 | Frame Shift Del (DEL) | VAF 29/157 reads (18%) | catalogued as rs769088263; called by mutect2, pindel, varscan2
- SHROOM3 | c.5773G>A p.V1925M | Missense Mutation (SNP) | VAF 88/340 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354812155, COSV99934647; called by muse, mutect2, varscan2
- SHROOM4 | c.1388del p.P463Lfs*23 | Frame Shift Del (DEL) | VAF 24/164 reads (15%) | catalogued as COSV56788246, COSV99173928; called by mutect2, varscan2
- SIDT1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs772935487, COSV53498863; called by muse, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 29/160 reads (18%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC18A1 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs200394019, COSV99368489, COSV99369007; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC22A7 | c.1075T>C p.F359L (on ENST00000372585 / NM_153320.2; = p.F357L on NM_006672.3) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs756333321; called by mutect2, varscan2
- SLC2A1 | c.1412del p.G471Efs*37 | Frame Shift Del (DEL) | VAF 49/252 reads (19%) | catalogued as CD1413229; called by mutect2, pindel, varscan2
- SLC34A3 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as rs761862841, COSV63186940; called by muse, mutect2, varscan2
- SLC36A1 | c.19C>T p.R7W | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs761378542, COSV99695810; called by muse, mutect2, varscan2
- SLC39A7 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs570973108; called by muse, mutect2, varscan2
- SLC5A8 | c.1075G>A p.A359T | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as COSV101610535; called by muse, mutect2, varscan2
- SLC6A12 | c.1703G>A p.R568H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs1271757007; called by muse, varscan2
- SLC6A7 | c.832del p.Q278Sfs*82 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | catalogued as COSV57939345; called by mutect2, pindel, varscan2
- SLCO3A1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs775241468, COSV59230207; called by muse, mutect2, varscan2
- SLF1 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1184700494; called by muse, mutect2, varscan2
- SLFN12 | c.548T>G p.V183G | Missense Mutation (SNP) | VAF 86/383 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV59225188; called by mutect2, varscan2
- SLFN14 | c.1225C>A p.L409I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.368); catalogued as COSV70570456; called by muse, mutect2, varscan2
- SLIT2 | c.3635G>A p.R1212Q | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs867063089, COSV56581050; called by muse, mutect2, varscan2
- SLITRK1 | c.134dup p.F47Lfs*30 | Frame Shift Ins (INS) | VAF 38/215 reads (18%) | catalogued as rs763682501; called by mutect2, varscan2
- SLITRK2 | c.1721G>A p.R574K | Missense Mutation (SNP) | VAF 20/191 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs782420604; called by muse, mutect2
- SMARCA4 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV60813310; called by muse, mutect2, varscan2
- SMC4 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as rs756108826, COSV61006818; called by muse, mutect2, varscan2
- SMC6 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV61174908; called by muse, mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 50/214 reads (23%) | catalogued as rs747405143; called by mutect2, varscan2
- SNX18 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV57990035; called by muse, mutect2, varscan2
- SOGA3 | c.722del p.G241Afs*133 | Frame Shift Del (DEL) | VAF 42/235 reads (18%) | catalogued as rs778091058, COSV100846885; called by mutect2, pindel, varscan2
- SOX13 | c.1559G>A p.R520Q | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313195109, COSV65826913, COSV65827351; called by muse, mutect2, varscan2
- SPAG16 | c.1873G>A p.G625S | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs371003630; called by muse, mutect2, varscan2
- SPATA2L | c.857C>A p.P286Q | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV57046260; called by muse, mutect2, varscan2
- SPEM2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs369322480; called by mutect2, varscan2
- SPG11 | c.6953G>A p.R2318H | Missense Mutation (SNP) | VAF 96/370 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as rs768408465, COSV55993338; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRPK1 | c.1610C>T p.T537M | Missense Mutation (SNP) | VAF 73/192 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs778938649; called by muse, mutect2, varscan2
- SRPRA | c.1867C>A p.L623I | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100141738; called by muse, mutect2, varscan2
- ST3GAL2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 18/83 reads (22%) | PolyPhen probably damaging (0.998); catalogued as rs759434739, COSV61595915; called by muse, mutect2, varscan2
- ST6GAL2 | c.871del p.R291Afs*24 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as COSV64526128, COSV64528793; called by mutect2, pindel, varscan2
- STAB2 | c.7349del p.P2450Lfs*4 | Frame Shift Del (DEL) | VAF 42/175 reads (24%) | catalogued as COSV101186457; called by mutect2, pindel, varscan2
- STARD9 | c.13996G>A p.A4666T | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.444); catalogued as rs768932589; called by muse, mutect2, varscan2
- STIM2 | c.1624C>T p.R542W | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.549); catalogued as rs753878084, COSV52842177; called by muse, mutect2, varscan2
- STK11IP | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs764933484; called by muse, mutect2, varscan2
- STK11IP | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV55247423; called by muse, varscan2
- SUGT1 | c.801A>C p.K267N (on ENST00000343788 / NM_001130912.3; = p.K235N on NM_006704.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1418625465; called by muse, mutect2, varscan2
- SULF1 | c.1029del p.F343Lfs*7 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | catalogued as rs773014665, COSV52672549; called by mutect2, pindel, varscan2
- SV2A | c.412del p.E138Rfs*39 | Frame Shift Del (DEL) | VAF 12/132 reads (9%) | catalogued as rs1553764068; called by mutect2, pindel
- SV2C | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs775165202, COSV59229887; called by muse, mutect2, varscan2
- SYCP1 | c.2642del p.K881Rfs*21 | Frame Shift Del (DEL) | VAF 22/112 reads (20%) | catalogued as rs776683356; called by mutect2, varscan2
- SYMPK | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 48/219 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762852760; called by muse, mutect2, varscan2
- SYNE2 | c.3491del p.N1164Mfs*15 | Frame Shift Del (DEL) | VAF 83/457 reads (18%) | catalogued as rs36002065; called by mutect2, pindel, varscan2
- SZT2 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1486824755; called by muse, mutect2, varscan2
- TAF1 | c.4994T>C p.V1665A (on ENST00000373790 / NM_138923.4; = p.V1686A on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as COSV52107198; called by muse, mutect2, varscan2
- TAS1R2 | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 62/272 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs748655290, COSV64745160; called by muse, mutect2, varscan2
- TBC1D10C | c.1281del p.I428Sfs*126 | Frame Shift Del (DEL) | VAF 31/141 reads (22%) | catalogued as rs756043635; called by mutect2, pindel, varscan2
- TBC1D8B | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761632565, COSV52180080; called by muse, mutect2, varscan2
- TBX22 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 24/301 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV64785128; called by muse, mutect2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | catalogued as rs754897911; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- TCEAL2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs974439123, COSV61197327; called by muse, mutect2, varscan2
- TCF20 | c.235T>C p.Y79H | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1569154785; called by muse, mutect2, varscan2
- TCHP | c.522del p.K174Nfs*26 | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | catalogued as rs763438715; called by mutect2, varscan2
- TCTN1 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs1201004771; called by muse, mutect2, varscan2
- TDRD3 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.462); catalogued as rs1393269238, COSV99540158; called by muse, mutect2
- TENT4B | c.704G>A p.R235Q (on ENST00000561678 / NM_001365323.2; = p.R220Q on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770123017, COSV62548292; called by muse, mutect2, varscan2
- TEX55 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.788); catalogued as rs758956113, COSV55210774; called by muse, mutect2, varscan2
- TEX9 | c.655-2A>G p.X219_splice | Splice Site (SNP) | VAF 52/192 reads (27%) | catalogued as rs750649443; called by muse, varscan2
- TFRC | c.845A>G p.Y282C | Missense Mutation (SNP) | VAF 45/223 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64056969; called by muse, mutect2, varscan2
- TG | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as rs1256883610; called by muse, mutect2, varscan2
- TGIF2LX | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 95/496 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as COSV52215080, COSV52215374, COSV99383415; called by muse, mutect2, varscan2
- THADA | c.3137C>T p.A1046V | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375558518; called by muse, mutect2, varscan2
- THBS4 | c.2098G>T p.G700* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV63468852; called by muse, mutect2, varscan2
- THOP1 | c.1874C>T p.T625M | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as rs146226928; called by muse, mutect2, varscan2
- TJP2 | c.3182G>A p.G1061D | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as rs756375710, COSV55268399; called by muse, mutect2, varscan2
- TJP3 | c.2484del p.Y830Tfs*64 | Frame Shift Del (DEL) | VAF 31/105 reads (30%) | catalogued as rs748320679, COSV99515633; called by mutect2, pindel, varscan2
- TLE2 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs917041948; called by muse, mutect2, varscan2
- TLN2 | c.3377C>T p.T1126M | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as rs535939717, COSV100167904; called by muse, mutect2, varscan2
- TMED10 | c.411+5G>A | Splice Region (SNP) | VAF 38/166 reads (23%) | catalogued as rs1171510922; called by muse, mutect2, varscan2
- TMEM145 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 53/229 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV56625393; called by muse, mutect2, varscan2
- TMEM177 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs562270009, COSV55608155; called by muse, mutect2, varscan2
- TMEM30A | c.965del p.N322Ifs*23 | Frame Shift Del (DEL) | VAF 55/166 reads (33%) | catalogued as rs753980983; called by mutect2, pindel, varscan2
- TMEM45B | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs375699692; called by muse, mutect2, varscan2
- TMPRSS11E | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs375419198; called by muse, mutect2, varscan2
- TNNI1 | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100270426; called by muse, mutect2, varscan2
- TPCN2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as rs766724247; called by muse, mutect2, varscan2
- TPSAB1 | c.365T>C p.I122T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754556153; called by mutect2, varscan2
- TRA2A | c.799C>T p.R267* | Nonsense Mutation (SNP) | VAF 26/111 reads (23%) | catalogued as rs1470869416, COSV104396615; called by muse, mutect2, varscan2
- TRAF3 | c.416del p.N139Mfs*20 | Frame Shift Del (DEL) | VAF 73/338 reads (22%) | catalogued as rs1566789781; called by mutect2, pindel, varscan2
- TRAF7 | c.722del p.P241Rfs*5 | Frame Shift Del (DEL) | VAF 22/100 reads (22%) | catalogued as rs750035555; called by mutect2, varscan2
- TRAM1L1 | c.36del p.V13Ffs*128 | Frame Shift Del (DEL) | VAF 11/98 reads (11%) | catalogued as rs753182240; called by mutect2, pindel, varscan2
- TRAPPC12 | c.1646A>G p.Y549C | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as COSV60846781; called by muse, mutect2, varscan2
- TRBV19 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 58/272 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs371076167; called by muse, mutect2, varscan2
- TRIM62 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as rs1248361251; called by muse, mutect2, varscan2
- TRPA1 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 54/217 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139821338; called by muse, mutect2, varscan2
- TRPM1 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 85/439 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs780515306, COSV99855592; called by muse, mutect2, varscan2
- TRPM4 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs762477533; called by muse, mutect2, varscan2
- TSPOAP1 | c.1948C>T p.R650W | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as rs148012035; called by muse, varscan2
- TTBK1 | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.14); catalogued as rs369497771, COSV52491743; called by muse, mutect2, varscan2
- TTC23L | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771520055, COSV72205924; called by muse, mutect2, varscan2
- TTC28 | c.7141del p.A2381Lfs*5 | Frame Shift Del (DEL) | VAF 46/201 reads (23%) | catalogued as COSV101194734; called by mutect2, pindel, varscan2
- TTC3 | c.2334dup p.E779Rfs*18 | Frame Shift Ins (INS) | VAF 34/132 reads (26%) | catalogued as rs756650873; called by mutect2, varscan2
- TTC7B | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.181); catalogued as rs147330824; called by muse, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 26/190 reads (14%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.60148A>G p.I20050V (on ENST00000591111; = p.I12626V on NM_003319.4) | Missense Mutation (SNP) | VAF 42/202 reads (21%) | PolyPhen benign (0.28); catalogued as rs1305525889; called by muse, mutect2, varscan2
- TTN | c.33725del p.P11242Qfs*45 (on ENST00000591111; = p.P10315Qfs*45 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 59/309 reads (19%) | catalogued as COSV59920295, COSV59947848; called by mutect2, pindel, varscan2
- UBAP1L | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.015); catalogued as COSV101544058; called by muse, varscan2
- UBE2F | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs1479057654; called by muse, mutect2, varscan2
- UBE2O | c.3808C>T p.R1270W | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as rs778601048, COSV60062392; called by muse, mutect2, varscan2
- UBE2Q1 | c.101del p.G34Afs*8 | Frame Shift Del (DEL) | VAF 15/99 reads (15%) | catalogued as rs759160193; called by mutect2, varscan2
- UBE2S | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777458627; called by muse, mutect2, varscan2
- UBE4A | c.2336T>C p.M779T (on ENST00000252108 / NM_001204077.2; = p.M786T on NM_004788.4) | Missense Mutation (SNP) | VAF 65/255 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1391910279; called by muse, varscan2
- UGT1A4 | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV59392054; called by mutect2, varscan2
- UMODL1 | c.2138A>G p.N713S (on ENST00000408910 / NM_001004416.2; = p.N841S on NM_173568.3) | Missense Mutation (SNP) | VAF 38/163 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs774580638; called by muse, mutect2, varscan2
- VAX2 | c.719del p.P240Hfs*36 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs782186760; called by mutect2, pindel, varscan2
- VCAN | c.7511G>A p.S2504N | Missense Mutation (SNP) | VAF 61/301 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs553376710; called by mutect2, varscan2
- VGLL1 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV65702858; called by muse, mutect2, varscan2
- VIT | c.1027A>G p.T343A (on ENST00000389975 / NM_001177969.1; = p.T358A on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 66/219 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs1207606522; called by muse, varscan2
- VN1R2 | c.514G>T p.G172C | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); catalogued as COSV100447859; called by muse, mutect2, varscan2
- VPS13D | c.3911C>T p.T1304M | Missense Mutation (SNP) | VAF 56/226 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs772562383; called by muse, mutect2, varscan2
- VWA3A | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.082); catalogued as rs758832147, COSV67011343; called by muse, mutect2, varscan2
- VWA7 | c.212del p.P71Lfs*34 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | catalogued as rs1410246345, COSV100791785; called by mutect2, pindel, varscan2
- WASF3 | c.920del p.P307Rfs*28 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | catalogued as rs756173793; called by mutect2, varscan2
- WASL | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1231120773, COSV56132223; called by muse, mutect2, varscan2
- WDFY2 | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 44/205 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs750311985; called by muse, mutect2, varscan2
- WDR37 | c.160G>A p.V54I | Missense Mutation (SNP) | VAF 45/251 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs76988882; called by muse, mutect2, varscan2
- WDR4 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1161970791; called by muse, mutect2, varscan2
- WDR49 | c.887C>T p.T296I (on ENST00000308378 / NM_001366158.1; = p.T637I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.915); catalogued as COSV57711327; called by muse, mutect2, varscan2
- WDR73 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 49/203 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs774735599, COSV62411254; called by muse, mutect2, varscan2
- WDR81 | c.4771G>A p.G1591R (on ENST00000409644 / NM_001163809.2; = p.G540R on NM_152348.4) | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs761103438, COSV58487024; called by muse, mutect2, varscan2
- WDR90 | c.3031G>C p.A1011P | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs368701693, COSV53470820; called by mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 15/138 reads (11%) | catalogued as COSV53295493; called by mutect2, pindel
- WNT11 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 62/306 reads (20%) | catalogued as rs755075137, COSV59443645; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 45/257 reads (18%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WWC2 | c.3309G>T p.Q1103H | Missense Mutation (SNP) | VAF 70/277 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as COSV101331123; called by muse, mutect2, varscan2
2,015 further variants in this file (1,144 protein-altering or splice-affecting, 534 silent, 337 other) are not listed here.
